Somatic mutation profile of tumor specimen TARGET-20-PALGKX-09A (aliquot TARGET-20-PALGKX-09A-01D) from TARGET case TARGET-20-PALGKX, project TARGET-AML (Acute Myeloid Leukemia). Sex at birth: female; Vital status: Dead; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 12.9 years (4,723 days).
Specimen TARGET-20-PALGKX-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ae4c8a28-1fea-4f99-8bf2-ab181e221b3e.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-20-PALGKX-14A (Bone Marrow Normal), aliquot TARGET-20-PALGKX-14A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/31dbba17-65df-41a3-ad76-12442e4e7936

The open-access MAF lists 2 somatic variants for this specimen: 1 protein-altering or splice-affecting, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: 5'UTR 1, Missense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IKZF1 | c.1504C>T p.R502W | Missense Mutation (SNP) | VAF 56/100 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV58783116; called by muse, mutect2, varscan2
- HOXA5 | c.-12A>C | 5'UTR (SNP) | VAF 67/153 reads (44%) | called by muse, mutect2, varscan2
